CPTAC case C3L-05849 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/196391b3-b000-4293-a9c1-0181e063a4a5

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1955; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 64.3 years (23,490 days); Year of diagnosis: 2019; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T2; AJCC pathologic N: N2a; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC2; Tumor grade: G3; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,767 days (4.8 years); Progression or recurrence: no; Days to last follow up: 1,767 days (4.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 9.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 14; Lymph nodes tested: 22; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 385 days (1.1 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 385 days (1.1 years); Disease response: Complete Response; ECOG performance status: 0.
- Days to follow up: 743 days (2.0 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,108 days (3.0 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,420 days (3.9 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,767 days (4.8 years); Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Weight: 80 kg; Height: 165.1 cm; BMI: 29.35; Hormonal contraceptive use: Never Used.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-05849-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 12 days; Initial weight: 310 mg; Time between clamping and freezing: 17 minutes; Time between excision and freezing: 4 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-05849-22: Section location: endometrium; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-05849-12: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 12 days; Time between clamping and freezing: 17 minutes; Time between excision and freezing: 4 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-05849-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 12 days; Method of sample procurement: Blood Draw.
